CCDI case PBCICT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/06f5702e-1464-425e-8bf0-c5eeb34c4a25

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 5.9 years (2,159 days).

Biospecimens (3 samples)
- Sample 0DSS55: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSS5S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSS6A: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
